Somatic mutation profile of tumor specimen TARGET-20-PARGMH-03A (aliquot TARGET-20-PARGMH-03A-01D) from TARGET case TARGET-20-PARGMH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.1 years (6,615 days).
Specimen TARGET-20-PARGMH-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 516a090c-cbd4-414e-a3b3-64c7b902c790.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARGMH-14A (Bone Marrow Normal), aliquot TARGET-20-PARGMH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f269c126-714c-4a38-9511-f282e7c0a6c9

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1331A>T p.E444V | Missense Mutation (SNP) | VAF 65/280 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV54074517; called by muse, mutect2, varscan2
- THRAP3 | c.2335T>C p.S779P | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- NCAM1 | c.2131+3193del | Intron (DEL) | VAF 118/339 reads (35%) | called by mutect2, pindel, varscan2
